Gene-level copy-number profile of tumor specimen ALCH-B3JS-TTP1-A from ALCHEMIST case ALCH-B3JS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.4 years (24,264 days).
Specimen ALCH-B3JS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8430d9bd-440f-4e8d-b71c-111473a1ea89.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3JS-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/f93576a9-7d52-4a55-b6f9-8ffe923c79e5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 3,430; copy number 2: 53,194; copy number 3: 1,652; copy number 4: 35; copy number 5: 7.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,425,980–2,505,532, 3 genes: PLCH2, AL139246.1, AL139246.4.
- chr1:20,719,731–20,733,952, 2 genes: SH2D5, AL663074.1.
- chr1:36,084,094–36,125,222, 3 genes: TEKT2, ADPRS, COL8A2.
- chr2:131,821,987–131,832,031, 2 genes: AC103564.3, AC103564.1.
- chr3:62,814,382–62,814,491, 1 gene (within-gene range 0–2): RNU6-139P.
- chr3:126,973,065–126,976,426, 1 gene: AC011199.1.
- chr7:66,553,805–66,557,362, 3 genes (within-gene range 0–2): AC006001.4, SAPCD2P3, AC006001.1.
- chr11:494,512–507,300, 1 gene: RNH1.
- chr12:57,194,504–57,194,576, 1 gene (within-gene range 0–2): MIR1228.
- chr13:28,778,224–28,778,937, 2 genes: AL359741.1, POM121L13P.
- chr13:113,399,610–113,453,524, 1 gene (within-gene range 0–2): ADPRHL1.
- chr14:18,333,726–18,341,859, 1 gene: CR383658.1.
- chr15:25,172,635–25,225,284, 29 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr16:8,869,251–8,870,032, 1 gene: AC022167.4.
- chr16:83,968,632–84,002,776, 1 gene: NECAB2.
- chr17:8,310,241–8,322,514, 2 genes: ARHGEF15, AC135178.2.
- chr19:38,815,422–38,831,841, 1 gene (within-gene range 0–2): ECH1.
- chr19:38,820,166–38,823,223, 1 gene (within-gene range 0–2): AC104534.1.
- chr22:31,064,105–31,104,757, 2 genes (within-gene range 0–2): SMTN, AC005005.3.
- chr22:38,426,327–38,455,199, 2 genes (within-gene range 0–2): KCNJ4, Z97056.3.
- chr22:41,205,282–41,577,741, 15 genes (within-gene range 0–2): L3MBTL2, L3MBTL2-AS1, CHADL, RANGAP1, MIR6889, ZC3H7B, TEF, RNU6-495P, AL008582.1, TOB2, ACO2, PHF5A, POLR3H, AL023553.1, CSDC2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:74,650,231–74,760,692, 3 genes, copy number 5: GTF2I, AC211433.1, PHBP15.
- chr14:18,395,626–18,419,273, 2 genes, copy number 5: CR383658.2, BNIP3P6.
- chr16:1,612,337–1,677,908, 2 genes, copy number 5 (within-gene range 3–5): CRAMP1, Z97652.1.

Autosomal genes at a single copy (total copy number 1): 2,862. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
